TCGA case TCGA-08-0517 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: UCSF. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9773acd0-e8bf-4991-8913-53f0d2adfc72

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 34 years; Vital status: Dead; Days to death: 1,785 days (4.9 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 35.0 years (12,771 days); Year of diagnosis: 1996; Method of diagnosis: Surgical Resection; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 16 days; Days to treatment end: 58 days; Treatment dose: 5,400 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine + Procarbazine + Vincristine; Initial disease status: Progressive Disease; Days to treatment start: 1,086 days (3.0 years); Days to treatment end: 1,359 days (3.7 years); Number of cycles: 6; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Isotretinoin; Initial disease status: Progressive Disease; Days to treatment end: 1,754 days (4.8 years); Treatment dose: 160 mg/day; Route of administration: Oral.
2. Recurrence of diagnosis 1 (Glioblastoma). Age at diagnosis: 37.8 years (13,795 days); Days to diagnosis: 1,024 days (2.8 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 1,049 days (2.9 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS; Radiation Therapy, NOS, for recurrent disease.

Follow-up (5 entries)
- Day 1,024 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 1,024 days (2.8 years).
- Days to follow up: 1,770 days (4.8 years); Disease response: With Tumor.
- Days to follow up: 1,785 days (4.9 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.
- Karnofsky performance status: 80; Timepoint: Post Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-08-0517-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.6; Intermediate dimension: 0.4; Shortest dimension: 0.4.
  Slide TCGA-08-0517-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
  Slide TCGA-08-0517-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-08-0517-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: Yes; Method initial path diagnosis: Tumor resection; Performance status timing: Post-Adjuvant Therapy.
- Drug treatment 1: Pharmaceutical therapy drug name: Accutane; Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: PO.
- Drug treatment 2: Pharmaceutical therapy drug name: Procarbazine/CCNU/Vincristine; Therapy regimen: Progression.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,785 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,785 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,024 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-08-0517-01): tumor purity 0.93, ploidy 1.88, whole-genome doublings 0 (call status: legacy_call).
